Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5GF, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5GF-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, Squamous
cell NOS 867013

Site: @ Lung, lower lobe
CB4.3
JW217/13

Histopathology Report

HISTORY

Left lower lobe; L/N 10; Bronchial Ca left lower lobe; patient has mild pulmonary fibrosis

MACROSCOPIC

Two specimens submitted.

1. The first specimen is labelled 'left lower lobe' and consists of a lobe of lung measuring 125 x 80 x 65 mm. No parietal pleura is included. The visceral pleural surface shows focal puckering of the lateral surface. The area of puckering measures 25 mm in diameter. Several enlarged hilar nodes are identified. They measure between 15 mm and 30 mm in diameter. Serial slicing shows a solitary, ill-defined subpleural tumour measuring 24 x 10 x 22 mm. It is located immediately beneath the area of pleural puckering, and is 33 mm from the bronchial resection margin. The non-neoplastic lung shows extensive dilatation of the subpleural airspaces toward the apex. Some of the dilated airspaces measure up to 35 mm in maximum diameter. Toward the base, there is diffuse firmness of the lung parenchyma, which is associated with grey discoloration. [1A, shave bronchial resection margin; 1B, shave vascular resection margin; 1C-1D, composite section of tumour and associated puckered pleura; 1E-1F, composite section of full face of tumour and its relation to the pleura; 1G, rep TS of tumour; 1H-1I, 2 rep TS of apical lung showing extensively dilated airspaces; 1J, rep TS of basal lung showing the firm grey area; 1K-1N, hilar lymph nodes (1 node per block).]

2. The second specimen is labelled 'left no 10 lymph node' and consists of two fragments of brown to black tissue measuring 16 x 8 x 7 mm and 9 x 6 x 6 mm. Each of the fragments is bisected. [BIT, 2A.]

MICROSCOPIC

1: Sections show a poorly differentiated squamous cell carcinoma. The tumour is subpleural and measures 27mm in maximum dimension [1G]. Pleural invasion is identified [1G]. There is no vascular invasion or lymphatic permeation is seen. No perineural invasion is identified. The lesion is well clear of the bronchial resection margin. There is metastatic carcinoma within all the identified hilar lymph nodes, with some of the lymph nodes showing transected tumour deposits at the margins. The adjacent lung shows evidence of emphysema and fibrosis with a usual interstitial pneumonia (UIP)-like pattern. Fibrosis is most pronounced in the base of the lobe, where there is honeycomb change with fibroblastic foci.

2: The No. 10 lymph node does not show evidence of metastases and contains carbon pigment and birefringent material consistent with silica.

SUMMARY

[page 2 of 2]
1&2. Lung, left lower lobe and lymph nodes:

- Poorly differentiated squamous cell carcinoma; 27mm in maximal dimension.
- No lymphatic invasion, blood vessel and perineural invasion.
- Pleural invasion identified; clear of bronchial margin.
- Metastatic carcinoma in hilar lymph nodes.
- No evidence of malignancy in No 10 lymph node (Specimen 2).
- T2a N1 [AJCC 7th ed].
- Non-neoplastic lung: Emphysema, fibrosis with UIP-like pattern.

T-28000 M-80703 M-78000 P1-03000

ANATOMICAL PATHOLOGY

Source: NCI Genomic Data Commons file fca62422-cf17-4d18-b751-bef26ff5c8bb (TCGA-77-A5GF.DCAA6959-3E03-4CE6-83C3-02287C3E390B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).